Somatic mutation profile of tumor specimen MP2PRT-PAURXV-TMP1-A (aliquot MP2PRT-PAURXV-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAURXV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,274 days).
Specimen MP2PRT-PAURXV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00d0d6b9-c687-4db9-8ec4-24a4794ba9c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURXV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURXV-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2753d84f-2270-4f48-9565-838dc22ee26c

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLA-DRA | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 424/979 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs946681808; called by muse, mutect2, varscan2
- KIF17 | c.3050G>A p.R1017H | Missense Mutation (SNP) | VAF 189/424 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs377443985, COSV56121803; called by muse, mutect2, varscan2
- OLIG3 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 246/654 reads (38%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.699); catalogued as rs373454434; called by muse, mutect2, varscan2
- PREX2 | c.4132A>C p.K1378Q | Missense Mutation (SNP) | VAF 217/453 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1448746073; called by muse, mutect2, varscan2
- SYT9 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 265/609 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV59618617; called by muse, mutect2, varscan2
- Z83844.2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 201/468 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779554139, COSV60929505; called by muse, mutect2, varscan2
- HSP90AB1 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB7A | c.1540del p.A514Pfs*43 | Frame Shift Del (DEL) | VAF 133/346 reads (38%) | called by mutect2, pindel, varscan2
